Somatic mutation profile of tumor specimen MMRF_2209_1_BM_CD138pos (aliquot MMRF_2209_1_BM_CD138pos_T1_KHS5U_L08816) from MMRF case MMRF_2209, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,934 days).
Specimen MMRF_2209_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ff841c9-04cf-4dce-83d3-220feae8fd4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2209_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2209_1_PB_Whole_C2_KHS5U_L08792; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6af882f3-60d9-471a-8a79-9d3ee6f1f17c

The open-access MAF lists 134 somatic variants for this specimen: 54 protein-altering or splice-affecting, 17 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 38, Missense Mutation 37, Silent 17, Intron 10, Nonsense Mutation 7, 5'UTR 5, 3'Flank 4, Frame Shift Del 4, RNA 4, Splice Site 2, In Frame Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICRA | c.2213C>G p.P738R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1235964967; called by muse, mutect2, varscan2
- CACNA1G | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs761563364; called by muse, mutect2, varscan2
- CILP2 | c.3118G>A p.A1040T | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1292007287; called by muse, mutect2
- DOCK9 | c.3160C>T p.P1054S (on ENST00000376460 / NM_001366676.2; = p.P1055S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV59645064; called by muse, mutect2
- EPHB4 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768500840; called by muse, mutect2, varscan2
- GYPC | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99391631; called by muse, mutect2
- IGHV1-69D | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 72/102 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1457115666; called by muse, mutect2
- IGLL5 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs531309531, COSV73250375, COSV73250928; called by muse, varscan2
- LMBR1 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV62220056; called by muse, mutect2, varscan2
- LRRC74A | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1195894350; called by muse, mutect2, varscan2
- NODAL | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758790389; called by muse, mutect2, varscan2
- NRXN1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1244838607; called by muse, mutect2, varscan2
- RBM10 | c.911T>C p.L304S | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61308689; called by muse, mutect2, varscan2
- RREB1 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs1211553369; called by muse, mutect2, varscan2
- TRAF3 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 15/21 reads (71%) | catalogued as COSV61026797; called by muse, mutect2, varscan2
- TRDN | c.1050dup p.E351Rfs*7 | Frame Shift Ins (INS) | VAF 18/32 reads (56%) | catalogued as rs753514580; called by mutect2, varscan2
- UGT3A2 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242466765; called by muse, mutect2, varscan2
- USH1C | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV50014049; called by muse, mutect2, varscan2
- ACSS3 | c.1773T>A p.D591E | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ASDURF | c.243del p.E82Nfs*5 | Frame Shift Del (DEL) | VAF 56/216 reads (26%) | called by mutect2, pindel, varscan2
- ATP5F1A | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | called by mutect2, varscan2
- BAG3 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCKAR | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST10 | c.603T>A p.D201E | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DDX3X | c.610C>T p.P204S (on ENST00000399959; = p.P205S on NM_001356.5) | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DTX1 | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- FAM174A | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM177B | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- GABRA4 | c.1297C>G p.P433A | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- GPRASP1 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HROB | c.1883-1G>T p.X628_splice | Splice Site (SNP) | VAF 63/176 reads (36%) | called by muse, mutect2, varscan2
- IGHD3-22 | c.23T>C p.L8S | Missense Mutation (SNP) | VAF 10/10 reads (100%) | called by muse, varscan2
- IGHD3-22 | c.2T>G p.V1G | Missense Mutation (SNP) | VAF 12/12 reads (100%) | called by muse, varscan2
- IGHV1-69D | c.221T>A p.F74Y | Missense Mutation (SNP) | VAF 75/102 reads (74%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- ITGA3 | c.2459G>A p.W820* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- KIAA2012 | c.223T>G p.S75A | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LNPEP | c.690A>C p.K230N | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- LRP1B | c.2088G>A p.W696* | Nonsense Mutation (SNP) | VAF 80/255 reads (31%) | called by muse, mutect2, varscan2
- MASP2 | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2
- NFKBIA | c.802_807del p.Q268_L269del | In Frame Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- NPY4R2 | c.714C>G p.Y238* | Nonsense Mutation (SNP) | VAF 63/373 reads (17%) | called by muse, mutect2, varscan2
- PARP6 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN13 | c.5566G>T p.A1856S (on ENST00000411767 / NM_080683.3; = p.A1837S on NM_006264.3) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PTPRM | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 55/162 reads (34%) | called by muse, mutect2, varscan2
- RFTN1 | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 49/161 reads (30%) | called by muse, mutect2, varscan2
- RSPO3 | c.642del p.G215Efs*69 | Frame Shift Del (DEL) | VAF 40/76 reads (53%) | called by mutect2, varscan2
- SFRP4 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.01); called by muse, mutect2
- SLC25A48-AS1 | n.203G>T | Splice Region (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- SPI1 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2
- TASOR | c.2174C>T p.A725V (on ENST00000355628 / NM_001365636.2; = p.A329V on NM_015224.3) | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- TENT5C | c.410_433del p.A137_K144del | In Frame Del (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel, varscan2
- TENT5C | c.669del p.F223Lfs*8 | Frame Shift Del (DEL) | VAF 16/147 reads (11%) | called by mutect2, pindel, varscan2
- TM2D1 | c.166+2T>A p.X56_splice | Splice Site (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- TRAF3 | c.795_804del p.E265Dfs*15 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD18A | c.708C>T p.A236= | Silent (SNP) | VAF 92/317 reads (29%) | catalogued as rs1176954822; called by muse, mutect2, varscan2
- EEA1 | c.9G>A p.R3= | Silent (SNP) | VAF 55/203 reads (27%) | called by muse, mutect2, varscan2
- FAM174A | c.87C>A p.P29= | Silent (SNP) | VAF 47/145 reads (32%) | catalogued as rs1241321848; called by muse, mutect2, varscan2
- GALNT6 | c.417G>A p.K139= | Silent (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.57C>A p.S19= | Silent (SNP) | VAF 15/15 reads (100%) | called by mutect2, varscan2
- IGHV2-70 | c.246A>T p.T82= | Silent (SNP) | VAF 57/62 reads (92%) | catalogued as rs367734033; called by muse, mutect2, varscan2
- IGLV3-1 | c.123C>T p.C41= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs61731695; called by muse, varscan2
- IL17RD | c.54C>T p.L18= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- NOD2 | c.2529G>A p.E843= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- OR2T10 | c.486C>A p.I162= | Silent (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- OR5F1 | c.417C>A p.T139= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs201523946, COSV53546357, COSV99558312; called by muse, mutect2, varscan2
- SHANK1 | c.6219G>A p.S2073= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as rs752181137, COSV53250557; called by muse, mutect2, varscan2
- SNX33 | c.1356C>T p.A452= | Silent (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- UBA7 | c.1197G>A p.G399= | Silent (SNP) | VAF 33/129 reads (26%) | called by muse, mutect2, varscan2
- WNT11 | c.510G>A p.K170= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ZBTB8OS | c.73T>C p.L25= | Silent (SNP) | VAF 99/217 reads (46%) | catalogued as rs1438102310; called by muse, mutect2, varscan2
- ZNF350 | c.759G>A p.Q253= | Silent (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- ABL2 | c.*7485A>C | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- AC016705.2 | n.280G>A | RNA (SNP) | VAF 58/1030 reads (6%) | called by muse, mutect2
- AC098650.1 | c.*115+16064C>T | Intron (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2
- ACTN1 | c.105+802A>T | Intron (SNP) | VAF 48/167 reads (29%) | called by muse, mutect2, varscan2
- AGPS | c.*3350A>G | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- AHSA1 | c.-24G>A | 5'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- AL353804.7 | chrX:73848874 T>C | 5'Flank (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- AR | c.1885+3598G>A | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- AR | c.1885+3599A>G | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- ARHGAP31 | c.*865G>A | 3'UTR (SNP) | VAF 37/47 reads (79%) | called by muse, mutect2, varscan2
- ATG4B | c.*970G>A | 3'UTR (SNP) | VAF 78/214 reads (36%) | called by muse, mutect2, varscan2
- ATM | c.*5C>G | 3'UTR (SNP) | VAF 19/308 reads (6%) | called by muse, mutect2
- ATPAF1 | chr1:46632914 A>T | 3'Flank (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- BMP5 | c.*1257T>C | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- BPNT2 | c.*5018C>T | 3'UTR (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- C16orf72 | c.*4571C>T | 3'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as rs892758824; called by muse, varscan2
- C20orf181 | n.272G>T | RNA (SNP) | VAF 46/163 reads (28%) | called by muse, mutect2, varscan2
- CCDC50 | c.*2820G>A | 3'UTR (SNP) | VAF 7/109 reads (6%) | catalogued as rs1311913967; called by muse, mutect2
- CCDC90B | c.*2774G>A | 3'UTR (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- CMIP | c.478-6694C>T | Intron (SNP) | VAF 59/132 reads (45%) | called by muse, mutect2, varscan2
- CYP19A1 | c.*494G>T | 3'UTR (SNP) | VAF 120/262 reads (46%) | called by muse, mutect2, varscan2
- DNAL1 | c.*188_*197del | 3'UTR (DEL) | VAF 32/34 reads (94%) | called by mutect2, pindel, varscan2
- FAM131B | c.*1707A>C | 3'UTR (SNP) | VAF 87/228 reads (38%) | called by muse, mutect2, varscan2
- FAM81A | c.*1697C>T | 3'UTR (SNP) | VAF 10/143 reads (7%) | called by muse, mutect2
- IGLON5 | c.*219C>A | 3'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- IREB2 | c.*1448T>A | 3'UTR (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- KCNAB1 | c.276-130564G>A | Intron (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- LCE3E | c.*200C>A | 3'UTR (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- LCMT1 | c.-8C>T | 5'UTR (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- LEP | c.*518T>A | 3'UTR (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- LINC01036 | n.93T>G | RNA (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- LTB | c.162+61G>A | Intron (SNP) | VAF 26/57 reads (46%) | catalogued as rs932462715; called by muse, mutect2, varscan2
- MACC1 | chr7:20140369 C>T | 3'Flank (SNP) | VAF 5/63 reads (8%) | catalogued as rs1404783875; called by muse, mutect2
- MARF1 | c.*715C>A | 3'UTR (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- MAX | chr14:65102535 G>A | 5'Flank (SNP) | VAF 38/63 reads (60%) | catalogued as rs1394080903; called by muse, mutect2, varscan2
- MBLAC2 | c.*2734A>G | 3'UTR (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- MEF2A | c.*873T>C | 3'UTR (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- MEIS2 | c.-752G>A | 5'UTR (SNP) | VAF 37/147 reads (25%) | catalogued as rs550701321; called by muse, mutect2, varscan2
- METTL5 | c.592-272A>G | Intron (SNP) | VAF 19/98 reads (19%) | catalogued as rs1403664094; called by muse, mutect2, varscan2
- MOBP | chr3:39514532 C>A | 3'Flank (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- NCALD | c.*2425T>C | 3'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- OTUD5 | c.*917C>T | 3'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- PPHLN1 | chr12:42448280 T>A | 3'Flank (SNP) | VAF 43/91 reads (47%) | called by muse, varscan2
- PPP6R3 | c.*2074A>T | 3'UTR (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- PRTG | c.*6627A>T | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- RAG1 | c.*2432_*2433insCTGCACGA | 3'UTR (INS) | VAF 23/68 reads (34%) | called by mutect2, pindel, varscan2
- RNPEPL1 | c.1175-43C>T | Intron (SNP) | VAF 110/388 reads (28%) | called by muse, mutect2, varscan2
- RPP25L | c.*190T>C | 3'UTR (SNP) | VAF 13/204 reads (6%) | called by muse, mutect2
- RPS4XP21 | n.642C>T | RNA (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- RRN3 | c.*460G>A | 3'UTR (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- SLC24A3 | c.*669G>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- SLC6A4 | c.*1266C>A | 3'UTR (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- SMCO4 | c.*159G>A | 3'UTR (SNP) | VAF 42/165 reads (25%) | catalogued as rs750871404; called by muse, mutect2, varscan2
- SP6 | c.*1424G>A | 3'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- STAT1 | c.*1455_*1456del | 3'UTR (DEL) | VAF 21/73 reads (29%) | catalogued as rs1311321881; called by mutect2, pindel, varscan2
- TBL1XR1 | c.*2234T>A | 3'UTR (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- TMEM154 | c.*3325A>G | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- TMEM260 | c.-159G>A | 5'UTR (SNP) | VAF 21/25 reads (84%) | called by muse, mutect2, varscan2
- TTI2 | c.-159C>T | 5'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*167_*178del | 3'UTR (DEL) | VAF 24/53 reads (45%) | called by mutect2, pindel, varscan2
- UGT8 | c.*1661G>T | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.*2939C>G | 3'UTR (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- ZNF662 | c.34+57T>A | Intron (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
